TARGET case TARGET-15-PARUIF — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/8f2e28ba-6912-4824-bef4-26941c72afcc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 1,634 days (4.5 years).

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 6.2 years (2,255 days).

Biospecimens (2 samples)
- Sample TARGET-15-PARUIF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-PARUIF-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
